Somatic mutation profile of tumor specimen 0DJHH7 from CCDI case PBBWPX, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 17.8 years (6,517 days).
Specimen 0DJHH7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3d7bb454-b13d-4038-9a72-8a372fcbaa57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJHE1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76130e16-a58b-4d9a-b1b9-e7c5bc3ba95b

The open-access MAF lists 19 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 2, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA3 | c.3319G>A p.A1107T | Missense Mutation (SNP) | VAF 53/468 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs140114428, COSV57053333; called by muse, mutect2, varscan2
- B3GNT8 | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 240/548 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as rs756191178; called by muse, mutect2, varscan2
- CACNA1I | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100360705; called by muse, mutect2, varscan2
- DCSTAMP | c.607A>G p.T203A | Missense Mutation (SNP) | VAF 168/440 reads (38%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV99886629; called by muse, mutect2
- DPP6 | c.940G>A p.A314T (on ENST00000377770 / NM_001364500.2; = p.A252T on NM_001936.5) | Missense Mutation (SNP) | VAF 141/632 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs778166866, COSV59599853; called by muse, mutect2, varscan2
- HDAC9 | c.1064C>T p.T355M | Missense Mutation (SNP) | VAF 89/439 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.27); catalogued as rs367766754; called by muse, mutect2, varscan2
- IFT172 | c.4385C>A p.A1462E | Missense Mutation (SNP) | VAF 366/682 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99562747; called by muse, mutect2, varscan2
- SIX6 | c.234G>T p.K78N | Missense Mutation (SNP) | VAF 543/874 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.058); catalogued as rs1447414831; called by muse, mutect2, varscan2
- VIT | c.928C>T p.R310* (on ENST00000389975 / NM_001177969.1; = p.R325* on NM_053276.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 108/672 reads (16%) | catalogued as rs776206880, COSV64897972; called by muse, varscan2
- ZNF274 | c.1577A>C p.K526T (on ENST00000610905; = p.K421T on NM_016324.3) | Missense Mutation (SNP) | VAF 89/700 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); catalogued as COSV58766235; called by muse, mutect2, varscan2
- ABI2 | c.49C>G p.R17G | Missense Mutation (SNP) | VAF 122/265 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.779); called by muse, varscan2
- C4orf54 | c.3446C>T p.S1149F | Missense Mutation (SNP) | VAF 254/360 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HEPACAM2 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 57/347 reads (16%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1109 | c.7563T>A p.S2521R | Missense Mutation (SNP) | VAF 291/440 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- MRPL51 | c.83T>G p.V28G | Missense Mutation (SNP) | VAF 22/478 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.018); called by muse, mutect2
- NCAM2 | c.2495A>G p.E832G | Missense Mutation (SNP) | VAF 216/654 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ABI2 | c.48C>G p.R16= | Silent (SNP) | VAF 122/264 reads (46%) | called by muse, varscan2
- EXO5 | c.867C>T p.I289= | Silent (SNP) | VAF 92/324 reads (28%) | called by muse, mutect2, varscan2
- CFAP65 | c.-2-93C>G | Intron (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
